Surgical pathology report (de-identified scan), TCGA case TCGA-21-1083, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1083-01A (Primary Tumor).

[page 1 of 5]
Clinical History/Diagnosis: Not entered.

Source of Specimen(s):

A: L4 LN

B: R4 LN

C: R2 LN

D: LEVEL 7 LN

E: ADDITIONAL R4 LN

F: CYTOLOGY

G: LEVEL ELEVEN LYMPH NODE

H: LEVEL SIX LYMPH NODE

I: LEVEL FIVE LYMPH NODE

J: LEFT UPPER LOBE

Gross Description:

GROSS DESCRIPTION: Received in one part.

SOURCE OF TISSUE: 1 - Labeled #1, "L4 lymph node".

FROZEN SECTION DIAGNOSIS: 1FS - NO TUMOR SEEN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation are three gray-black, anthracotic stained lymph nodes, 0.3 to 0.4cm. in greatest dimension. They are submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

DESIGNATION OF SECTIONS: 1FS

SUMMARY OF SECTIONS: FS-3.

SOURCE OF TISSUE: 2 - Labeled #2, "R4 lymph node".

FROZEN SECTION DIAGNOSIS: 2FS - NO TUMOR SEEN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation are two gray-black, anthracotic stained tissue fragments, 0.3cm and 0.4cm in greatest dimension. They are submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

DESIGNATION OF SECTIONS: 2FS

SUMMARY OF SECTIONS: FS-2.

[page 2 of 5]
SOURCE OF TISSUE: 3 - Labeled #3, "R2 lymph node".

FROZEN SECTION DIAGNOSIS: 3FS - NO TUMOR SEEN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation is a 0.4cm gray-black, anthracotic stained tissue fragment. It is submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

DESIGNATION OF SECTIONS: 3FS

SUMMARY OF SECTIONS: FS-1.

SOURCE OF TISSUE: 4 - Labeled #4, "level 7 lymph node".

FROZEN SECTION DIAGNOSIS: 4FS - NO TUMOR SEEN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation are two gray-tan, irregular soft tissue fragments, 0.2 and 0.3cm in greatest dimension. They are submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

DESIGNATION OF SECTIONS: 4FS

SUMMARY OF SECTIONS: FS-2.

SOURCE OF TISSUE: 5 - Labeled #5, "additional R4 lymph nodes".

FROZEN SECTION DIAGNOSIS: 5FS - NO TUMOR SEEN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation is a 0.8cm gray-black, anthracotic stained tissue fragment. It is submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

DESIGNATION OF SECTIONS: 5FS

SUMMARY OF SECTIONS: FS-1.

SOURCE OF TISSUE: 6 - CYTOLOGY SPECIMEN.

SOURCE OF TISSUE: 7 - Labeled #7, "level 11 lymph node".

GROSS DESCRIPTION: Received fresh is a 1.4 x 1.0 x 0.6cm gray-black, anthracotic stained lymph node. It is trisected and entirely submitted on one block.

[page 3 of 5]
DESIGNATION OF SECTIONS: 7

SUMMARY OF SECTIONS: Undesignated - 3.

SOURCE OF TISSUE: 8 - Labeled #8, "level 6 lymph node".

GROSS DESCRIPTION: Received fresh is a 1.5cm in greatest dimension, gray-black, anthracotic stained lymph node with attached adipose tissue. It is bisected and entirely submitted in one block.

DESIGNATION OF SECTIONS: 8

SUMMARY OF SECTIONS: Undesignated - 2.

SOURCE OF TISSUE: 9 - Labeled #9, "level 5 lymph node".

GROSS DESCRIPTION: Received fresh is a 1.0 x 1.0 x 0.4cm gray-black, anthracotic stained lymph node with attached adipose tissue. It is bisected and entirely submitted in one block.

DESIGNATION OF SECTIONS: 9

SUMMARY OF SECTIONS: Undesignated - 1.

*

SOURCE OF TISSUE: 10 - Labeled #10, "left upper lobe".

GROSS DESCRIPTION: Received fresh is a 335 gram, 24.5 x 14.0 x 3.5cm left upper lobectomy of lung. It is covered by a pink to red-purple, focally anthracotic stained pleura, having up to 0.6cm of attached bronchus. In the superior/inferior segment, there is a 2.6 x 1.8 x 1.6cm firm mass. The cut surfaces are tan, gritty, having irregular borders. This lies approximately 3.0cm from the hilar structures. The overlying pleura is glistening and umbilicated. The remaining cut surfaces of the lung range from tan-pink to crepitant to areas which are red-purple, soft and glistening. There are multiple palpable, hilar lymph nodes, 0.5 to 2.0cm in greatest dimension. The cut surfaces of each are gray-black and anthracotic stained. A representative section of each lymph node is submitted. Representative sections are submitted in ten blocks.

DESIGNATION OF SECTIONS: 10A - bronchial and vascular margins, 10B thru 10E - tumor with inked pleural margin, 10F thru 10G - random lung sections, 10H thru 10J - hilar lymph nodes.

[page 4 of 5]
SUMMARY OF SECTIONS: 10A-5, 10B-1, 10C-1, 10D-1, 10E-1, 10F-1, 10G-2, 10H-3, 10I-2, 10J-2.

Final Diagnosis:

DIAGNOSIS:

1. LYMPH NODE, L4, BIOPSY:

- THREE LYMPH NODES ALL NEGATIVE FOR TUMOR (0/3).

2. LYMPH NODE, R4, BIOPSY:

- TWO LYMPH NODES BOTH NEGATIVE FOR TUMOR (0/2).

3. LYMPH NODE, R2, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1).

4. LYMPH NODE, LEVEL 7, BIOPSY:

- TWO LYMPH NODES BOTH NEGATIVE FOR TUMOR (0/2).

5. LYMPH NODE, ADDITIONAL R4, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1).

6. CYTOLOGY.

7. LYMPH NODE, LEVEL 11, SIDE NOT SPECIFIED, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1).

8. LYMPH NODE, LEVEL 6, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1).

9. LYMPH NODE, LEVEL 5, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1).

10. LUNG, LEFT UPPER LOBE, LOBECTOMY:

- SQUAMOUS CELL (EPIDERMOID) CARCINOMA, NON-KERATINIZING TYPE, POORLY

DIFFERENTIATED (GRADE III).

- MAXIMUM DIMENSION OF THE TUMOR IS: 2.6CM.

- LYMPHATIC INVASION BY TUMOR IS ABSENT.

- VENOUS INVASION BY TUMOR IS ABSENT.

- ARTERIAL INVASION BY TUMOR IS ABSENT.

- INVASION INTO BUT NOT THROUGH THE PLEURA BY TUMOR IS ABSENT.

- TUMOR NECROSIS IS MODERATE.

- SURGICAL MARGIN ARE UNINVOLVED BY TUMOR.

- NON-NEOPLASTIC LUNG TISSUE SHOWS EMPHYSEMA.

[page 5 of 5]
- TOTAL NUMBER OF NODES EXAMINED IS: 19
- TOTAL NUMBER OF POSITIVE NODES IS: 0

STAGING "T" DATA: T1

"N" DATA: N-0

Source: NCI Genomic Data Commons file f1eeb4d0-8aaf-4a7a-b9da-4286ed5538f0 (TCGA-21-1083.568A237A-00C3-4160-A471-3ED3623CA233.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).